Somatic mutation profile of tumor specimen TCGA-GV-A3JW-01A (aliquot TCGA-GV-A3JW-01A-11D-A20D-08) from TCGA case TCGA-GV-A3JW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 74.2 years (27,091 days).
Specimen TCGA-GV-A3JW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a41f375-6920-433e-b11a-820bdc5792a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A3JW-10A (Blood Derived Normal), aliquot TCGA-GV-A3JW-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6e418fb-ebd5-48c1-945e-da283fba2375

The open-access MAF lists 78 somatic variants for this specimen: 59 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 18, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 56/65 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC11 | c.1883G>A p.G628E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62324616; called by muse, mutect2
- ABCC11 | c.1882G>T p.G628* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100750444; called by muse, mutect2
- ADAMTS6 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs766393767, COSV66862215; called by muse, mutect2, varscan2
- AKAP11 | c.3746C>G p.S1249* | Nonsense Mutation (SNP) | VAF 18/23 reads (78%) | catalogued as COSV50299632; called by muse, mutect2, varscan2
- AOAH | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51746075, COSV99332047; called by muse, mutect2, varscan2
- C5 | c.3523C>A p.L1175M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV56329983; called by mutect2, varscan2
- C8A | c.1223-1G>A p.X408_splice | Splice Site (SNP) | VAF 19/65 reads (29%) | catalogued as COSV63485573; called by muse, mutect2, varscan2
- CHD6 | c.5728G>C p.D1910H | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1159515732, COSV64688533; called by muse, mutect2, varscan2
- COL6A6 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as COSV62027685, COSV62031231; called by muse, mutect2, varscan2
- CPT1C | c.2294G>A p.G765E | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV54920822; called by muse, mutect2, varscan2
- CPVL | c.1303G>C p.A435P | Missense Mutation (SNP) | VAF 200/433 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV55305363; called by muse, varscan2
- DDX4 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV61756115; called by muse, mutect2, varscan2
- DDX4 | c.1606C>G p.R536G | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.526); catalogued as COSV61756124; called by muse, mutect2, varscan2
- DMGDH | c.2433G>C p.K811N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs200584827, COSV54866346; called by muse, mutect2, varscan2
- DNM3 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs201627857; called by muse, mutect2, varscan2
- ECPAS | c.180T>G p.N60K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV52202696; called by muse, mutect2, varscan2
- ENPP2 | c.1324G>C p.E442Q (on ENST00000075322 / NM_001040092.3; = p.E494Q on NM_006209.5) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50023817; called by muse, mutect2, varscan2
- GNPNAT1 | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV53592057; called by muse, mutect2, varscan2
- GPAT2 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs779378670, COSV64003728; called by muse, mutect2, varscan2
- HCN1 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as COSV57524543; called by muse, mutect2, varscan2
- HERC2 | c.6785C>T p.P2262L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs751972944; called by muse, mutect2
- HNRNPDL | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 82/295 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.559); catalogued as rs752710041, COSV55022200, COSV99787105; called by muse, mutect2, varscan2
- HOMEZ | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV62536966, COSV62537348; called by muse, mutect2, varscan2
- ICAM5 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV55748248; called by muse, mutect2, varscan2
- IFNAR2 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.876); catalogued as COSV59750022; called by muse, mutect2, varscan2
- IRAK2 | c.1024T>G p.L342V | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56533653; called by muse, mutect2, varscan2
- IRS2 | c.1897G>A p.G633R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.209); catalogued as rs760629200, COSV65479842; called by muse, mutect2, varscan2
- KIF11 | c.2504C>G p.S835C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV53272064; called by muse, mutect2, varscan2
- MRC1 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 130/284 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs372055031; called by muse, mutect2, varscan2
- MTA1 | c.2034G>C p.K678N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV58758764; called by muse, mutect2, varscan2
- MTMR6 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV67809056; called by muse, mutect2, varscan2
- MYO5A | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 82/602 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62562521; called by muse, mutect2, varscan2
- NHLRC1 | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61481714; called by muse, mutect2, varscan2
- NOD1 | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 40/600 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.207); catalogued as rs771682319, COSV56113703; called by muse, mutect2
- NUP98 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61435395; called by muse, mutect2, varscan2
- OR52B6 | c.125A>C p.Q42P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV61448065; called by muse, mutect2, varscan2
- OR6N2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751838454, COSV59410585, COSV59412494; called by muse, mutect2, varscan2
- OR6X1 | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV60009688, COSV60010128; called by muse, mutect2, varscan2
- PAN2 | c.2704G>A p.D902N (on ENST00000425394 / NM_001127460.3; = p.D898N on NM_014871.5) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV57755006; called by muse, mutect2, varscan2
- PCDHA2 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as COSV65364392; called by muse, mutect2, varscan2
- PGAM1 | c.445C>G p.Q149E | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58355902; called by muse, mutect2, varscan2
- PROX1 | c.1930A>C p.N644H | Missense Mutation (SNP) | VAF 75/85 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54781358; called by muse, mutect2, varscan2
- PXYLP1 | c.914A>G p.N305S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.829); catalogued as COSV53891994; called by muse, mutect2, varscan2
- RAB12 | c.287+2T>C p.X96_splice | Splice Site (SNP) | VAF 54/174 reads (31%) | catalogued as COSV61398969; called by muse, mutect2, varscan2
- RPAIN | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56709492; called by muse, mutect2, varscan2
- SEC13 | c.946G>C p.E316Q (on ENST00000350697 / NM_183352.3; = p.E319Q on NM_030673.4) | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV61602115; called by muse, mutect2
- SEZ6L2 | c.2489-1G>C p.X830_splice (on ENST00000308713 / NM_001114099.3; = p.X773_splice on NM_012410.4) | Splice Site (SNP) | VAF 20/107 reads (19%) | catalogued as COSV58101428; called by muse, mutect2, varscan2
- SGSM2 | c.2392G>A p.D798N (on ENST00000426855 / NM_001098509.2; = p.D843N on NM_014853.3) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52159815; called by muse, mutect2, varscan2
- SLC37A2 | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53523605; called by muse, mutect2, varscan2
- TCOF1 | c.1881G>C p.M627I (on ENST00000377797 / NM_001135243.1; = p.M550I on NM_000356.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV60351260; called by muse, mutect2, varscan2
- TEX2 | c.2962A>C p.M988L (on ENST00000583097 / NM_001288733.2; = p.M995L on NM_018469.5) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV51983523; called by muse, mutect2, varscan2
- ZNF395 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV60429607, COSV60430698; called by muse, mutect2, varscan2
- ZNF768 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1326977832, COSV63323358; called by muse, mutect2, varscan2
- ZNF768 | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV53224319; called by muse, mutect2, varscan2
- ZNF768 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.452); catalogued as rs370495340, COSV53224153; called by muse, varscan2
- CYP3A7 | c.921T>G p.Y307* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- MRC1 | c.1155G>C p.R385S | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.174); called by muse, mutect2
- ZNF513 | c.1146_1147del p.H382Qfs*3 | Frame Shift Del (DEL) | VAF 44/196 reads (22%) | called by pindel, varscan2
- BMP2K | c.3294C>T p.V1098= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV55010838; called by muse, mutect2
- BPTF | c.7116G>A p.Q2372= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV58841898; called by muse, mutect2, varscan2
- CYFIP2 | c.2889C>T p.S963= (on ENST00000616178 / NM_001291722.2; = p.S938= on NM_014376.4) | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV59045168; called by muse, mutect2, varscan2
- DYNC2I2 | c.762G>T p.L254= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- EDEM1 | c.1368C>T p.I456= | Silent (SNP) | VAF 61/176 reads (35%) | catalogued as COSV56582957, COSV56583634; called by muse, mutect2, varscan2
- FLII | c.1185G>A p.S395= | Silent (SNP) | VAF 50/101 reads (50%) | catalogued as rs145214604; called by muse, mutect2, varscan2
- IL18R1 | c.1605G>A p.L535= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV52125973; called by muse, mutect2, varscan2
- KCNB1 | c.183C>T p.R61= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1476243158, COSV65569719; called by muse, mutect2
- KLHL26 | c.687G>A p.A229= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs150852328; called by muse, mutect2, varscan2
- PCDHGA9 | c.1848C>T p.L616= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs369141362; called by muse, mutect2, varscan2
- PDCD6IP | c.801G>A p.Q267= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV56244348; called by muse, mutect2, varscan2
- PLD2 | c.1260G>A p.L420= | Silent (SNP) | VAF 53/238 reads (22%) | catalogued as COSV54007741, COSV99562101; called by muse, mutect2, varscan2
- SLFN13 | c.1482G>A p.L494= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV53193090; called by muse, mutect2
- SMOC1 | c.186C>A p.S62= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV62762434; called by muse, mutect2, varscan2
- TGM1 | c.21C>T p.S7= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs150913268, COSV52864252; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF329 | c.1149C>T p.N383= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as COSV63772989; called by muse, mutect2, varscan2
- ZNF747 | c.117C>T p.F39= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV53224332; called by muse, mutect2, varscan2
- ZNF84 | c.1926C>T p.L642= | Silent (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
- ADAM20 | c.-139C>T | 5'UTR (SNP) | VAF 73/134 reads (54%) | catalogued as COSV56455687; called by muse, mutect2, varscan2
